Somatic mutation profile of tumor specimen 0DS0ZW from CCDI case PBCHHD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.4 years (148 days).
Specimen 0DS0ZW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d34ebab-ec5f-41ef-ace0-be7d4ae380c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0ZC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/557bb20a-2532-4357-bd48-c26ba9ffffb1

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Splice Site 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA1210 | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 62/470 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYH11 | c.3963+2T>C p.X1321_splice | Splice Site (SNP) | VAF 73/464 reads (16%) | called by muse, mutect2, varscan2
